Somatic mutation profile of tumor specimen ALCH-B25S-TTP1-A (aliquot ALCH-B25S-TTP1-A-1-0-D-A774-36) from ALCHEMIST case ALCH-B25S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.8 years (25,481 days).
Specimen ALCH-B25S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb7aa18-c848-4188-8e56-7a98858e6d24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B25S-NB1-A (Blood Derived Normal), aliquot ALCH-B25S-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/472bc31e-6c2c-456c-8a8c-594d4c441124

The open-access MAF lists 1,623 somatic variants for this specimen: 1,081 protein-altering or splice-affecting, 332 silent, 210 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 915, Silent 332, Intron 102, Nonsense Mutation 82, RNA 39, Splice Site 28, Frame Shift Del 27, 5'UTR 23, Splice Region 21, 5'Flank 21, 3'UTR 18, 3'Flank 7.

Variants (750 of 1,623; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.16129G>T p.G5377* | Nonsense Mutation (SNP) | VAF 70/405 reads (17%) | catalogued as rs1561790371; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 50/760 reads (7%) | catalogued as rs1554610284; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 123/737 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2581C>T p.L861F | Missense Mutation (SNP) | VAF 138/973 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99711731; called by muse, mutect2, varscan2
- ACKR1 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63671680; called by muse, mutect2, varscan2
- ADAMTS6 | c.2885A>T p.Q962L | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV58682220; called by muse, mutect2, varscan2
- ADCY1 | c.3197G>T p.R1066M | Missense Mutation (SNP) | VAF 106/586 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV52030637; called by muse, mutect2
- ADGRE1 | c.1072A>T p.S358C | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1309963328; called by muse, mutect2, varscan2
- ADGRG4 | c.7597C>A p.H2533N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as rs373053622; called by muse, mutect2, varscan2
- ADGRV1 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67988626; called by muse, mutect2, varscan2
- AK5 | c.1318G>A p.V440I (on ENST00000354567 / NM_174858.3; = p.V414I on NM_012093.4) | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759165576, COSV60970735; called by muse, mutect2
- AL121899.2 | c.942del p.N315Tfs*44 | Frame Shift Del (DEL) | VAF 53/374 reads (14%) | catalogued as COSV67351694; called by mutect2, pindel, varscan2
- AL133500.1 | c.1565C>A p.A522E | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious, low confidence (0.03); catalogued as COSV99860384; called by muse, mutect2, varscan2
- ALX4 | c.1082A>T p.Q361L | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs772445432; called by muse, mutect2
- AMER1 | c.1891del p.R631Efs*22 | Frame Shift Del (DEL) | VAF 80/548 reads (15%) | catalogued as COSV57653855, COSV57662082; called by mutect2, pindel, varscan2
- AMER1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 28/436 reads (6%) | catalogued as COSV57668525; called by muse, mutect2
- AMTN | c.-15G>A | Splice Region (SNP) | VAF 55/361 reads (15%) | catalogued as rs1354164201; called by muse, mutect2, varscan2
- ANGPT1 | c.582A>T p.L194F | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV52445042; called by muse, mutect2
- ANK1 | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 185/726 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV55880752; called by muse, mutect2, varscan2
- ANK3 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV55073287; called by muse, mutect2, varscan2
- ANKRD27 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 122/675 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100042965; called by muse, mutect2, varscan2
- ANKRD30B | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100745800; called by muse, mutect2, varscan2
- ANKRD30B | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs748111206; called by muse, mutect2
- ANTXR1 | c.295A>T p.R99* | Nonsense Mutation (SNP) | VAF 101/736 reads (14%) | catalogued as COSV58012689; called by muse, mutect2, varscan2
- APOB | c.12052G>T p.D4018Y | Missense Mutation (SNP) | VAF 86/597 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV51926124, COSV51949199; called by muse, mutect2, varscan2
- APOB | c.3086T>A p.L1029* | Nonsense Mutation (SNP) | VAF 126/928 reads (14%) | catalogued as rs765763526; called by muse, mutect2, varscan2
- APOL1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs1041251036; called by muse, mutect2, varscan2
- AQP10 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV61475787; called by muse, mutect2, varscan2
- ARHGAP4 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 90/423 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV100604311; called by muse, mutect2, varscan2
- ARSG | c.901+1G>T p.X301_splice | Splice Site (SNP) | VAF 34/328 reads (10%) | catalogued as COSV71593598; called by muse, mutect2, varscan2
- ASTN2 | c.3407G>T p.C1136F (on ENST00000313400 / NM_001365069.1; = p.C1085F on NM_014010.5) | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56012955; called by muse, mutect2, varscan2
- ASXL2 | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV55455509; called by muse, mutect2
- ATG2A | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs565394394; called by muse, mutect2, varscan2
- ATP7A | c.2221C>A p.H741N | Missense Mutation (SNP) | VAF 83/769 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58446545; called by muse, mutect2, varscan2
- AVPR1A | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54546173, COSV54547962; called by muse, mutect2, varscan2
- B3GALT2 | c.506C>G p.A169G | Missense Mutation (SNP) | VAF 72/483 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66464533; called by muse, mutect2, varscan2
- BAIAP3 | c.169C>A p.R57S | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV60982323; called by muse, mutect2, varscan2
- BCHE | c.1409T>A p.I470N | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100011933; called by muse, mutect2
- BCHE | c.420G>T p.W140C | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013030; called by muse, mutect2
- BCKDHB | c.792A>T p.E264D | Missense Mutation (SNP) | VAF 118/871 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1378605375; called by muse, varscan2
- BCORL1 | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV54398600; called by muse, mutect2
- BMPR2 | c.2678G>T p.R893L | Missense Mutation (SNP) | VAF 89/460 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.598); catalogued as COSV101001811; called by muse, mutect2, varscan2
- BOD1L1 | c.8368G>A p.V2790I | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1345501738; called by muse, varscan2
- BRD4 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV54588002; called by muse, mutect2, varscan2
- BRSK1 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs758425269, COSV100474753, COSV58669292; called by muse, mutect2, varscan2
- BSN | c.3550G>A p.A1184T | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV56529075; called by muse, mutect2, varscan2
- BTBD3 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 72/428 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.918); catalogued as rs755076085; called by muse, mutect2, varscan2
- C1QTNF1 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.403); catalogued as COSV59260387; called by muse, mutect2, varscan2
- C2orf16 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1312307557; called by muse, mutect2
- CADM2 | c.995C>A p.A332E (on ENST00000407528 / NM_001167674.2; = p.A334E on NM_153184.4) | Missense Mutation (SNP) | VAF 52/560 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.968); catalogued as COSV67385337; called by muse, mutect2
- CBLL2 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375566609; called by muse, mutect2, varscan2
- CCDC22 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140671002; called by muse, mutect2
- CCDC88B | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1000383749; called by muse, varscan2
- CDH7 | c.9G>T p.L3F | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.202); catalogued as COSV100541131; called by muse, mutect2
- CDH7 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 75/502 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.245); catalogued as COSV100542832; called by muse, mutect2, varscan2
- CDH9 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 43/347 reads (12%) | catalogued as COSV50366850; called by muse, mutect2, varscan2
- CDHR3 | c.1051A>T p.S351C | Missense Mutation (SNP) | VAF 107/712 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs754156071; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4673G>T p.R1558L | Missense Mutation (SNP) | VAF 95/618 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs377338416; called by muse, mutect2, varscan2
- CDKN2A | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58693485; called by muse, mutect2, varscan2
- CEACAM8 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99747487; called by muse, mutect2
- CHRM2 | c.593del p.P198Qfs*2 | Frame Shift Del (DEL) | VAF 163/1252 reads (13%) | catalogued as COSV57768235; called by mutect2, pindel, varscan2
- CHRM2 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 60/505 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as COSV57775055, COSV57781065; called by muse, mutect2, varscan2
- CHRNB1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as rs757646406; called by muse, mutect2, varscan2
- CKAP5 | c.4045G>T p.G1349* | Nonsense Mutation (SNP) | VAF 22/198 reads (11%) | catalogued as COSV100371125; called by muse, mutect2
- CNTN4 | c.2281G>T p.V761L | Missense Mutation (SNP) | VAF 66/447 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV61871407, COSV61875748; called by muse, mutect2, varscan2
- CNTNAP2 | c.1478G>C p.G493A | Missense Mutation (SNP) | VAF 89/743 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62213362; called by muse, mutect2, varscan2
- COL19A1 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV59591959; called by muse, mutect2
- COL4A2 | c.4160C>A p.A1387D | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs749680471; called by muse, mutect2, varscan2
- CPS1 | c.3037G>A p.V1013M | Missense Mutation (SNP) | VAF 30/655 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as CD036036; called by muse, mutect2
- CREBRF | c.1222+7T>C | Splice Region (SNP) | VAF 19/116 reads (16%) | catalogued as rs768300159; called by muse, mutect2, varscan2
- CSMD3 | c.8399T>A p.L2800H (on ENST00000297405 / NM_001363185.1; = p.L2631H on NM_052900.3) | Missense Mutation (SNP) | VAF 43/553 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs752568327; called by muse, mutect2
- CSMD3 | c.8057C>A p.T2686N (on ENST00000297405 / NM_001363185.1; = p.T2582N on NM_052900.3) | Missense Mutation (SNP) | VAF 44/818 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as COSV99825552; called by muse, mutect2
- CSMD3 | c.4511A>G p.Q1504R (on ENST00000297405 / NM_001363185.1; = p.Q1400R on NM_052900.3) | Missense Mutation (SNP) | VAF 94/496 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs984497006, COSV52324804; called by muse, mutect2, varscan2
- CSMD3 | c.2504C>G p.P835R (on ENST00000297405 / NM_001363185.1; = p.P731R on NM_052900.3) | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV52105719, COSV52280066; called by muse, mutect2
- CSMD3 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52221127; called by muse, mutect2
- CT47B1 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 112/627 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.261); catalogued as rs774721836; called by muse, mutect2, varscan2
- CTNNA2 | c.2486A>T p.D829V | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs1374054926; called by muse, mutect2
- CTNNA2 | c.2683G>T p.G895W (on ENST00000402739 / NM_001282597.3; = p.G847W on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/667 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58170124; called by muse, mutect2
- CTNND2 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.715); catalogued as rs763230842; called by muse, mutect2, varscan2
- CUX2 | c.4045C>T p.L1349F | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs944201096; called by muse, mutect2, varscan2
- CYLC2 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.624); catalogued as rs1023449636; called by muse, mutect2, varscan2
- DCAF4L2 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 69/341 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100151059; called by muse, mutect2, varscan2
- DCC | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 282/1392 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs141878982; called by muse, mutect2, varscan2
- DCLK1 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV55170754, COSV99712874; called by muse, mutect2, varscan2
- DCST2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 142/554 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99791841; called by muse, mutect2, varscan2
- DCTN1 | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 112/554 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100721101, COSV62620765; called by muse, mutect2, varscan2
- DCUN1D1 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 18/248 reads (7%) | catalogued as COSV53045901; called by muse, mutect2
- DDO | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.231); catalogued as rs758675079, COSV64470562; called by muse, mutect2, varscan2
- DNAH1 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV70228837, COSV70237946; called by muse, mutect2, varscan2
- DOCK2 | c.4964G>C p.C1655S | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.175); catalogued as COSV56992683; called by muse, mutect2, varscan2
- DOCK8 | c.4317T>A p.D1439E | Missense Mutation (SNP) | VAF 139/649 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1162190219; called by muse, mutect2, varscan2
- DOK1 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV51208323; called by muse, mutect2, varscan2
- DPYSL5 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56512987; called by muse, mutect2, varscan2
- DRG2 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.663); catalogued as rs1468447694; called by muse, mutect2, varscan2
- DSCAML1 | c.1381A>T p.I461F (on ENST00000321322; = p.I401F on NM_020693.4) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs906471774; called by muse, mutect2, varscan2
- DSEL | c.1247C>A p.T416N | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.882); catalogued as COSV59494839; called by muse, mutect2
- DZIP1L | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as rs1478652932; called by muse, mutect2, varscan2
- EGFR | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 178/799 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV51837186; called by muse, mutect2, varscan2
- EIF3C | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 52/672 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.067); catalogued as rs745410532; called by muse, mutect2
- EPHA3 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 88/784 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV60728676; called by muse, mutect2, varscan2
- EPHA4 | c.2150G>T p.R717I | Missense Mutation (SNP) | VAF 69/434 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs370645355; called by muse, mutect2, varscan2
- EPHA5 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 55/434 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV56643165; called by muse, mutect2, varscan2
- EPHA6 | c.2084C>A p.P695Q (on ENST00000389672 / NM_001080448.3; = p.P87Q on NM_173655.4) | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV67595110; called by muse, mutect2, varscan2
- ERCC2 | c.1645G>T p.V549L | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV67266098; called by muse, mutect2, varscan2
- EVPLL | c.17A>T p.D6V | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1218819478; called by muse, mutect2, varscan2
- FAM124B | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs768991891, COSV99706208; called by muse, mutect2, varscan2
- FAM160A1 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1327272937; called by muse, mutect2
- FAM184B | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV53960162; called by muse, mutect2, varscan2
- FAM47A | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV60494276; called by muse, mutect2
- FAM47A | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV100649974, COSV60495260; called by muse, mutect2, varscan2
- FBXL7 | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as COSV61640843; called by muse, mutect2, varscan2
- FBXO6 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs747288004; called by muse, mutect2, varscan2
- FLG | c.1952A>G p.E651G | Missense Mutation (SNP) | VAF 219/974 reads (22%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.932); catalogued as rs772746955; called by muse, mutect2, varscan2
- FOXL1 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 37/402 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57213995; called by muse, mutect2
- FOXQ1 | c.1211G>C p.*404Sext*28 | Nonstop Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs1261963611; called by muse, mutect2, varscan2
- GABRA1 | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 46/796 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV50106803, COSV99196293; called by muse, mutect2
- GABRA2 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 88/978 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV62913637; called by muse, mutect2
- GCNT2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs769425044; called by muse, mutect2
- GDI1 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 118/483 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV63895580; called by muse, mutect2, varscan2
- GGN | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV99287309; called by muse, mutect2, varscan2
- GLI3 | c.2014G>C p.A672P | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.649); catalogued as COSV101230210; called by muse, mutect2
- GPM6A | c.796C>A p.H266N | Missense Mutation (SNP) | VAF 72/577 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV54549040; called by muse, mutect2, varscan2
- GPR141 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as rs984533010; called by muse, mutect2, varscan2
- GPRC5B | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs1457452132; called by muse, mutect2, varscan2
- GREB1 | c.5119G>T p.E1707* | Nonsense Mutation (SNP) | VAF 63/506 reads (12%) | catalogued as COSV52191351; called by muse, mutect2, varscan2
- GRIN3A | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 97/691 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV62452146; called by muse, mutect2, varscan2
- GRM7 | c.2173C>G p.P725A | Missense Mutation (SNP) | VAF 64/575 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV63163153; called by muse, mutect2, varscan2
- GUCY1A2 | c.2138C>G p.S713W | Missense Mutation (SNP) | VAF 116/967 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV56479237, COSV56485367; called by muse, mutect2, varscan2
- GUCY2F | c.3062G>T p.R1021L | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54300373; called by muse, mutect2, varscan2
- GYPB | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 53/538 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51628236; called by muse, mutect2
- GZMA | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57056677; called by muse, mutect2, varscan2
- H3-2 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 81/542 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.743); catalogued as rs1339644829; called by muse, mutect2, varscan2
- HCRTR2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 110/735 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV63799553; called by muse, mutect2, varscan2
- HDAC9 | c.2477del p.G826Vfs*45 | Frame Shift Del (DEL) | VAF 29/263 reads (11%) | catalogued as COSV67782480; called by mutect2, pindel
- HGSNAT | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs727503962, CM065255; called by muse, varscan2
- HMCN2 | c.13818G>A p.A4606= | Splice Region (SNP) | VAF 9/64 reads (14%) | catalogued as rs775188542; called by muse, mutect2
- HOXA1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99053186; called by muse, mutect2, varscan2
- HSD11B1 | c.357C>A p.N119K | Missense Mutation (SNP) | VAF 125/964 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54829847; called by muse, mutect2, varscan2
- HTR1A | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); catalogued as rs1293191104; called by muse, mutect2
- IARS1 | c.712G>T p.V238F | Missense Mutation (SNP) | VAF 91/534 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65113908; called by muse, mutect2, varscan2
- IBA57 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100812768; called by muse, mutect2, varscan2
- IGHMBP2 | c.925A>G p.K309E | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as rs200079527; ClinVar: uncertain significance; called by muse, mutect2
- IGHV1-24 | c.30G>C p.L10F | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs782143922; called by muse, mutect2
- IGHV3-23 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 56/1185 reads (5%) | catalogued as rs782358535; called by muse, mutect2
- INSM2 | c.1438C>G p.P480A | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs779133987; called by muse, mutect2, varscan2
- IRS4 | c.2861C>A p.S954* | Nonsense Mutation (SNP) | VAF 175/1102 reads (16%) | catalogued as COSV64532657; called by muse, mutect2, varscan2
- ITGA8 | c.1101C>G p.S367R | Missense Mutation (SNP) | VAF 93/599 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as rs759346104, COSV100959935; called by muse, mutect2, varscan2
- ITGBL1 | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 67/611 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66011636; called by muse, mutect2, varscan2
- ITPKB | c.1143G>T p.M381I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV55258289; called by muse, mutect2, varscan2
- JKAMP | c.683-1G>T p.X228_splice (on ENST00000554271 / NM_001284201.1; = p.X214_splice on NM_016475.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 68/351 reads (19%) | catalogued as COSV54200615, COSV99711736; called by muse, mutect2, varscan2
- KCNB2 | c.2039C>G p.A680G | Missense Mutation (SNP) | VAF 97/415 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); catalogued as COSV73052246; called by muse, mutect2, varscan2
- KCNC4 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV63924979; called by muse, mutect2, varscan2
- KCND2 | c.632C>A p.S211* | Nonsense Mutation (SNP) | VAF 24/374 reads (6%) | catalogued as COSV58579666; called by muse, mutect2
- KCNH8 | c.677G>A p.W226* | Nonsense Mutation (SNP) | VAF 88/932 reads (9%) | catalogued as rs752346433; called by muse, mutect2
- KCNQ3 | c.363G>T p.W121C | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV66473892; called by muse, mutect2, varscan2
- KCNS1 | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.07); catalogued as COSV60260591; called by muse, mutect2, varscan2
- KIAA0586 | c.3043G>T p.G1015C (on ENST00000619416 / NM_001244190.2; = p.G954C on NM_014749.5) | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV54171955, COSV54177992; called by muse, mutect2
- KIAA1958 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100515718; called by muse, mutect2, varscan2
- KLHL1 | c.1390G>C p.V464L | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs751182951; called by muse, mutect2, varscan2
- KLHL4 | c.1993G>T p.V665L | Missense Mutation (SNP) | VAF 86/743 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.633); catalogued as COSV64142281, COSV64149240; called by muse, mutect2, varscan2
- KLK15 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56825988; called by muse, mutect2, varscan2
- KRT6A | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 100/674 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760660499; called by muse, mutect2, varscan2
- KRT72 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1303979291; called by muse, mutect2, varscan2
- KRT77 | c.1627G>T p.G543C | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs760244596; called by muse, mutect2, varscan2
- KRTAP2-3 | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770063936; called by muse, mutect2, varscan2
- KRTAP5-6 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 54/293 reads (18%) | PolyPhen probably damaging (0.991); catalogued as rs758639920; called by muse, mutect2, varscan2
- LAMA1 | c.6886G>T p.G2296W | Missense Mutation (SNP) | VAF 118/771 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67536986; called by muse, mutect2, varscan2
- LAMP5 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55717004, COSV99855551; called by muse, mutect2
- LGI4 | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs747931967; called by muse, mutect2, varscan2
- LPP | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 76/615 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426753039; called by muse, mutect2, varscan2
- LRP1B | c.9848G>T p.G3283V | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101257379; called by muse, mutect2, varscan2
- LRP1B | c.6773G>C p.W2258S | Missense Mutation (SNP) | VAF 46/570 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.724); catalogued as COSV101260499, COSV67253870; called by muse, mutect2
- LRP2 | c.2804C>A p.A935D | Missense Mutation (SNP) | VAF 89/660 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV55559066; called by muse, mutect2, varscan2
- LRRC20 | c.359C>T p.P120L (on ENST00000355790 / NM_207119.3; = p.P70L on NM_018239.4) | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs755994482, COSV62937640; called by muse, mutect2
- LRRIQ1 | c.5117G>C p.R1706T | Missense Mutation (SNP) | VAF 109/593 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs766341199; called by muse, mutect2, varscan2
- LSAMP | c.88C>A p.R30S | Missense Mutation (SNP) | VAF 31/513 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV61303525; called by muse, mutect2
- LYZL2 | c.260G>T p.G87V (on ENST00000375318; = p.G41V on NM_183058.3) | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150609822; called by muse, mutect2, varscan2
- MACC1 | c.1259G>T p.W420L | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749492483; called by muse, mutect2, varscan2
- MAGEB10 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV63312590; called by muse, mutect2, varscan2
- MAGEC1 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 71/373 reads (19%) | catalogued as COSV53570341, COSV53583155; called by muse, mutect2, varscan2
- MAGEC2 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1319299913; called by muse, mutect2, varscan2
- MCM10 | c.940del p.T314Pfs*7 (on ENST00000484800 / NM_182751.3; = p.T313Pfs*7 on NM_018518.5) | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | catalogued as COSV66333281; called by mutect2, pindel, varscan2
- MDGA2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.711); catalogued as rs916720098; called by muse, mutect2
- MLH1 | c.1408A>T p.R470* | Nonsense Mutation (SNP) | VAF 42/648 reads (6%) | catalogued as CM093755; called by muse, mutect2
- MPPED2 | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 49/388 reads (13%) | catalogued as COSV63898272; called by muse, mutect2, varscan2
- MRTO4 | c.28+4G>A | Splice Region (SNP) | VAF 31/145 reads (21%) | catalogued as rs758749386; called by muse, mutect2, varscan2
- MS4A14 | c.464T>A p.F155Y | Missense Mutation (SNP) | VAF 96/567 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.072); catalogued as COSV100280139; called by muse, mutect2, varscan2
- MUC19 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 37/311 reads (12%) | catalogued as rs777205904; called by muse, mutect2, varscan2
- MUC3A | c.940del p.L314Yfs*5 | Frame Shift Del (DEL) | VAF 59/365 reads (16%) | catalogued as COSV60222562; called by mutect2, pindel, varscan2
- MUC5AC | c.14116C>A p.Q4706K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.528); catalogued as COSV100611576; called by muse, mutect2, varscan2
- MXRA5 | c.6317C>A p.T2106K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54242882, COSV99476892; called by muse, mutect2, varscan2
- MXRA5 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756893962, COSV54242793; called by muse, mutect2, varscan2
- MYCBP2 | c.13186G>A p.E4396K (on ENST00000357337; = p.E4434K on NM_015057.5) | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100629000; called by muse, mutect2, varscan2
- MYH2 | c.4328C>A p.A1443D | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV55434890, COSV55450091; called by muse, mutect2, varscan2
- MYH3 | c.4682G>C p.R1561P | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56863270; called by muse, mutect2, varscan2
- NAALADL2 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 31/202 reads (15%) | catalogued as COSV69153918; called by muse, mutect2, varscan2
- NADSYN1 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1192759262; called by muse, mutect2
- NAGPA | c.1413G>C p.L471F | Missense Mutation (SNP) | VAF 67/435 reads (15%) | PolyPhen benign (0.007); catalogued as rs371500762; called by muse, mutect2, varscan2
- NAV2 | c.3419C>A p.A1140D (on ENST00000396087 / NM_001244963.2; = p.A1117D on NM_145117.5) | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs756238748; called by muse, mutect2, varscan2
- NCKAP1L | c.2700G>T p.G900= | Splice Region (SNP) | VAF 24/115 reads (21%) | catalogued as rs1157574859, COSV99515338; called by muse, mutect2, varscan2
- NCKAP5 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV58480435; called by muse, mutect2
- NEURL4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.074); catalogued as rs1223818250; called by muse, mutect2
- NEXMIF | c.3650G>T p.R1217L | Missense Mutation (SNP) | VAF 139/894 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs143271748, COSV50028941; called by muse, mutect2, varscan2
- NHSL2 | c.1205G>T p.R402L (on ENST00000510661; = p.R768L on NM_001013627.2) | Missense Mutation (SNP) | VAF 104/546 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV65453308; called by muse, mutect2, varscan2
- NLRP13 | c.1910G>T p.R637L | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV61622910; called by muse, mutect2, varscan2
- NLRP3 | c.543G>C p.R181S | Missense Mutation (SNP) | VAF 87/566 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV60231096; called by muse, mutect2, varscan2
- NPBWR1 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs1432888179; called by muse, mutect2
- NPFFR2 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs764073931; called by muse, mutect2, varscan2
- NPHP4 | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs1048629373; called by muse, mutect2, varscan2
- NR2C1 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58008537; called by muse, mutect2
- NUP160 | c.1277+1G>T p.X426_splice | Splice Site (SNP) | VAF 41/247 reads (17%) | catalogued as COSV65854868; called by muse, mutect2, varscan2
- NXF3 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV67704464; called by muse, mutect2
- OPLAH | c.1768A>T p.M590L | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs1305280147; called by muse, mutect2, varscan2
- OR10A4 | c.904C>A p.L302M | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1351407061; called by muse, mutect2
- OR10K1 | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56871767; called by muse, mutect2, varscan2
- OR14C36 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58600972; called by muse, mutect2, varscan2
- OR1E2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 35/251 reads (14%) | catalogued as rs886691486; called by muse, mutect2, varscan2
- OR2L13 | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 42/718 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813731; called by muse, mutect2
- OR2L13 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 62/417 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63549238; called by muse, mutect2, varscan2
- OR2T1 | c.656G>C p.R219P | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.889); catalogued as COSV63541543; called by muse, mutect2, varscan2
- OR4C46 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs137991158, COSV100061123; called by muse, mutect2
- OR52A1 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 93/520 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV61093328; called by muse, mutect2, varscan2
- OR5P3 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1469048398; called by muse, mutect2
- OR6T1 | c.921G>T p.W307C | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100189799; called by muse, mutect2, varscan2
- ORM2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs1451137490, COSV56335482; called by muse, mutect2
- OSBPL7 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV50106964; called by muse, mutect2, varscan2
- OTOG | c.4234C>A p.R1412S | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV61133193; called by muse, mutect2
- OTOGL | c.4107del p.K1370Rfs*24 (on ENST00000547103; = p.K1361Rfs*24 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/322 reads (13%) | catalogued as rs779773339; called by mutect2, pindel, varscan2
- OTUD7A | c.1358C>A p.P453H (on ENST00000307050 / NM_001382637.1; = p.P446H on NM_130901.3) | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100192317; called by muse, mutect2, varscan2
- P2RX1 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 103/399 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs1490477117; called by muse, mutect2, varscan2
- PAPPA | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 72/441 reads (16%) | catalogued as COSV100073212, COSV60286024; called by muse, mutect2, varscan2
- PAPPA2 | c.4405C>A p.P1469T | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV62798585; called by muse, mutect2
- PCDH10 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52094003; called by muse, mutect2
- PCDH10 | c.3089A>G p.K1030R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs1197844898; called by muse, mutect2
- PCDH15 | c.5000C>G p.P1667R | Missense Mutation (SNP) | VAF 58/532 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.062); catalogued as COSV57259342; called by muse, mutect2, varscan2
- PCDH7 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780929028, COSV62343115; called by muse, mutect2
- PCDHGA2 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 81/467 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.259); catalogued as rs1357109474, COSV53929472; called by muse, mutect2, varscan2
- PCMTD1 | c.246G>T p.L82F | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62123099, COSV62126188; called by muse, mutect2
- PDE1B | c.478-1G>T p.X160_splice | Splice Site (SNP) | VAF 45/250 reads (18%) | catalogued as COSV54494176; called by muse, mutect2, varscan2
- PDE6B | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs370159647; called by muse, mutect2, varscan2
- PDE6B | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.239); catalogued as rs969407523; called by muse, mutect2, varscan2
- PEDS1 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59012832; called by muse, mutect2, varscan2
- PGK2 | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59165270; called by muse, mutect2, varscan2
- PGLYRP2 | c.1057C>A p.L353I | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as rs1423669863; called by muse, mutect2, varscan2
- PHEX | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 64/780 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV65079855; called by muse, mutect2
- PIAS3 | c.1439G>C p.G480A | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.351); catalogued as COSV57907323; called by muse, mutect2
- PIEZO2 | c.7696G>T p.A2566S | Missense Mutation (SNP) | VAF 75/527 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200520861, COSV53292464; called by muse, mutect2, varscan2
- PIEZO2 | c.7432A>T p.R2478W | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.235); catalogued as COSV53286958; called by muse, mutect2, varscan2
- PIEZO2 | c.5863T>A p.L1955M | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs112982077; ClinVar: uncertain significance; called by muse, mutect2
- PIGZ | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs767943913; called by muse, mutect2, varscan2
- PIK3CA | c.3068G>T p.R1023L | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55890113, COSV55959650; called by muse, mutect2, varscan2
- PIK3R6 | c.1734G>T p.R578S | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100266110; called by muse, mutect2, varscan2
- PKN1 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as rs770772273, COSV54397221, COSV54403488; called by muse, mutect2, varscan2
- PLD5 | c.482C>A p.P161Q (on ENST00000442594; = p.P99Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/575 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV59150037; called by muse, mutect2, varscan2
- PLOD2 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 45/653 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99282568; called by muse, mutect2
- PNMA3 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs782023071, COSV64722446; called by muse, mutect2, varscan2
- POLR1F | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs778894332; called by muse, mutect2, varscan2
- POTEF | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV62540919; called by muse, mutect2, varscan2
- POTEI | c.2272G>T p.A758S | Missense Mutation (SNP) | VAF 51/635 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs1281062294; called by muse, mutect2, varscan2
- PRDM16 | c.1767G>T p.E589D | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54592462; called by muse, mutect2, varscan2
- PRDM9 | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 279/1486 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs776657408, COSV57006202, COSV57012672; called by muse, mutect2, varscan2
- PRKX | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99468637; called by muse, mutect2, varscan2
- PXDNL | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 58/702 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs766095622; called by muse, mutect2
- PZP | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 78/572 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.325); catalogued as COSV54363494; called by muse, mutect2, varscan2
- RAB3GAP2 | c.692G>T p.C231F | Missense Mutation (SNP) | VAF 73/538 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52966193; called by muse, mutect2, varscan2
- RASA4 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1292699254; called by muse, mutect2
- RELN | c.6526C>A p.Q2176K | Missense Mutation (SNP) | VAF 24/582 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.569); catalogued as COSV59006649; called by muse, mutect2
- REV1 | c.976A>T p.T326S | Missense Mutation (SNP) | VAF 34/649 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV51490550; called by muse, mutect2
- RIMS1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 96/637 reads (15%) | catalogued as COSV99328345; called by muse, mutect2, varscan2
- RNF123 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs770811607, COSV59690825; called by muse, mutect2, varscan2
- RNPEPL1 | c.2026G>A p.G676S | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.534); catalogued as rs1384820499; called by muse, mutect2, varscan2
- RP1L1 | c.4445G>T p.G1482V | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.276); catalogued as COSV66752571; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 105/655 reads (16%) | catalogued as COSV59088468; called by muse, mutect2, varscan2
- RUNX1T1 | c.1101G>T p.M367I (on ENST00000265814 / NM_001198628.1; = p.M340I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/625 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99751817; called by muse, mutect2, varscan2
- RYR1 | c.3782G>T p.G1261V | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62111317; called by muse, mutect2, varscan2
- RYR2 | c.4762G>T p.V1588L | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV100768849; called by muse, mutect2, varscan2
- SAGE1 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 77/567 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV61016722; called by muse, mutect2, varscan2
- SCIN | c.2118G>T p.W706C (on ENST00000297029 / NM_001112706.3; = p.W459C on NM_033128.3) | Missense Mutation (SNP) | VAF 58/624 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51689106, COSV51693585; called by muse, mutect2
- SELE | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 73/456 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV60977983; called by muse, mutect2, varscan2
- SEMA5B | c.2131C>G p.R711G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52090025; called by muse, mutect2, varscan2
- SERPINB2 | c.712C>G p.R238G | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs758753971; called by muse, mutect2, varscan2
- SETBP1 | c.685G>T p.G229* | Nonsense Mutation (SNP) | VAF 94/510 reads (18%) | catalogued as COSV99955247; called by muse, mutect2, varscan2
- SETBP1 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 99/482 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99954319; called by muse, mutect2, varscan2
- SGCZ | c.235-1G>T p.X79_splice | Splice Site (SNP) | VAF 67/427 reads (16%) | catalogued as COSV66041369; called by muse, mutect2, varscan2
- SGPP1 | c.655A>T p.M219L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55976751; called by muse, mutect2, varscan2
- SH2D4B | c.973G>T p.A325S (on ENST00000646907; = p.A324S on NM_207372.2) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57892410; called by muse, mutect2, varscan2
- SH3TC2 | c.1947C>A p.H649Q | Missense Mutation (SNP) | VAF 63/367 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as COSV60462907; called by muse, mutect2, varscan2
- SHMT2 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV61073432; called by muse, mutect2, varscan2
- SI | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.49); catalogued as rs1471704915; called by muse, mutect2, varscan2
- SLC16A9 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 42/523 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68098728; called by muse, mutect2
- SLC17A6 | c.205del p.R69Afs*8 | Frame Shift Del (DEL) | VAF 80/685 reads (12%) | catalogued as COSV54135111; called by mutect2, pindel, varscan2
- SLC26A9 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772963778; called by muse, mutect2, varscan2
- SLC29A4 | c.1510T>C p.C504R | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV51873548; called by muse, mutect2, varscan2
- SLC5A4 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as rs1467333709; called by muse, mutect2
- SLC6A9 | c.1291C>A p.R431S (on ENST00000360584 / NM_201649.4; = p.R377S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.289); catalogued as COSV62210531, COSV62211040; called by muse, mutect2, varscan2
- SLIT1 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 68/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99822330; called by muse, mutect2, varscan2
- SLITRK2 | c.908G>C p.R303P | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59428955; called by muse, mutect2, varscan2
- SLITRK3 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 68/582 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99580071; called by muse, mutect2, varscan2
- SNCAIP | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs764747315, COSV99746927; called by muse, mutect2, varscan2
- SORCS1 | c.3374G>T p.R1125I | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV53839346; called by muse, mutect2, varscan2
- SORCS1 | c.2614G>C p.D872H | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV53876248; called by muse, mutect2, varscan2
- SPATA18 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs546839772; called by muse, mutect2, varscan2
- SPATA31D3 | c.2262C>A p.H754Q | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as rs766883847; called by mutect2, varscan2
- ST8SIA1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1393888665; called by muse, mutect2, varscan2
- STAG3 | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs560843443; called by muse, mutect2, varscan2
- STK31 | c.2057G>C p.R686T | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1286876299; called by muse, mutect2
- SYNJ1 | c.3705G>T p.P1235= | Splice Region (SNP) | VAF 73/372 reads (20%) | catalogued as COSV100449361; called by muse, mutect2, varscan2
- TASP1 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.376); catalogued as COSV61814555; called by muse, mutect2, varscan2
- TCL1A | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV68086063; called by muse, mutect2, varscan2
- TGIF2LX | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 40/859 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV99383280; called by muse, mutect2
- TKTL2 | c.1556C>A p.A519D | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777092894, COSV54918938; called by muse, mutect2
- TLL2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV63571163; called by muse, mutect2
- TMEM132C | c.2457C>A p.N819K | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs541757300; called by muse, mutect2, varscan2
- TMEM200A | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51654106; called by muse, mutect2
- TOPAZ1 | c.4427C>T p.T1476I | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV59064321; called by muse, mutect2, varscan2
- TRPM5 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763435755; called by muse, mutect2, varscan2
- TRPM6 | c.356A>T p.K119I | Missense Mutation (SNP) | VAF 85/577 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV62504836; called by muse, mutect2, varscan2
- TRPM8 | c.609G>T p.R203S | Missense Mutation (SNP) | VAF 42/828 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61221436; called by muse, mutect2
- TRPM8 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100224671; called by muse, mutect2
- TRRAP | c.1841A>T p.Y614F | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV62841653; called by muse, mutect2, varscan2
- TSHZ3 | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53683580, COSV99551251; called by muse, mutect2, varscan2
- TTN | c.24941C>A p.A8314D (on ENST00000591111; = p.A7387D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/178 reads (5%) | PolyPhen benign (0.006); catalogued as COSV60417906; called by muse, mutect2
- TTN | c.3230G>T p.G1077V (on ENST00000591111; = p.G1031V on NM_003319.4) | Missense Mutation (SNP) | VAF 137/780 reads (18%) | PolyPhen probably damaging (0.916); catalogued as COSV60339959; called by muse, mutect2, varscan2
- TTYH2 | c.1116G>T p.K372N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1296012925; called by muse, mutect2, varscan2
- UBE2A | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV100660522; called by muse, mutect2
- UBE3D | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 21/389 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV52755403; called by muse, mutect2
- UGT1A4 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as rs1309137091; called by muse, mutect2
- ULBP2 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 79/495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186843807, COSV66265834; called by muse, mutect2, varscan2
- UNC80 | c.2732G>C p.R911P | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55890443, COSV55909079; called by muse, mutect2
- USH2A | c.10061T>A p.V3354E | Missense Mutation (SNP) | VAF 122/1080 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1325811823; called by muse, mutect2, varscan2
- USH2A | c.9425G>T p.G3142V | Missense Mutation (SNP) | VAF 64/576 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1003254008; called by muse, mutect2, varscan2
- USH2A | c.7138C>T p.L2380F | Missense Mutation (SNP) | VAF 22/479 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as rs1308006303; called by muse, mutect2
- USP47 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.19); catalogued as rs889546704; called by muse, mutect2
- VPS13D | c.5463C>G p.I1821M | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs929610313; called by muse, mutect2
- VWA3B | c.2783C>A p.S928Y | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV68245873; called by muse, mutect2, varscan2
- VWA3B | c.3218C>T p.T1073I | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV69034189, COSV69034235; called by muse, mutect2
- VWA5B1 | c.2989A>G p.T997A (on ENST00000375079; = p.T992A on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1368634510; called by muse, mutect2, varscan2
- YIF1A | c.486-4G>A | Splice Region (SNP) | VAF 30/149 reads (20%) | catalogued as rs1180028167; called by muse, mutect2, varscan2
- ZBBX | c.1918C>A p.L640I | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV56802222; called by muse, mutect2, varscan2
- ZBTB16 | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as COSV100252329; called by muse, mutect2, varscan2
- ZFHX4 | c.1738G>C p.G580R | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV51499450; called by muse, mutect2, varscan2
- ZFHX4 | c.8186A>G p.Y2729C | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs1334168350; called by muse, mutect2, varscan2
- ZFP30 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 40/348 reads (11%) | catalogued as rs972640897; called by muse, mutect2, varscan2
- ZNF157 | c.1366C>A p.R456S | Missense Mutation (SNP) | VAF 39/402 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65659100, COSV65659358; called by muse, mutect2, varscan2
- ZNF302 | c.980A>T p.Q327L (on ENST00000627982; = p.Q248L on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/686 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1280528798; called by muse, mutect2
- ZNF560 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.869); catalogued as rs1172470361; called by muse, mutect2, varscan2
- ZNF607 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 57/290 reads (20%) | catalogued as COSV62205789; called by muse, mutect2, varscan2
- ZNF729 | c.2740G>T p.G914C | Missense Mutation (SNP) | VAF 105/838 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100675357; called by muse, mutect2, varscan2
- ZNF735 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as COSV70036164; called by muse, mutect2, varscan2
- ZNF804B | c.1172A>T p.E391V | Missense Mutation (SNP) | VAF 101/835 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as rs1457368269; called by muse, mutect2, varscan2
- ZNF804B | c.3674C>A p.S1225Y | Missense Mutation (SNP) | VAF 54/451 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV60817134; called by muse, mutect2, varscan2
- ABCB1 | c.2986C>A p.P996T | Missense Mutation (SNP) | VAF 164/1192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ABCG8 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 73/394 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- AC242842.3 | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 72/1478 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACAD11 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- ACAP3 | c.1583A>T p.E528V | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ACBD6 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 107/1023 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACE | c.3859A>T p.S1287C | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ACE2 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ACSM5 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ACTC1 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACTN3 | c.2182C>A p.R728S | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAM18 | c.581A>T p.K194I | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS20 | c.2176G>T p.V726F | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADAMTSL1 | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2
- ADCY2 | c.2776C>A p.L926I | Missense Mutation (SNP) | VAF 100/877 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADGRB3 | c.3898C>G p.Q1300E | Missense Mutation (SNP) | VAF 74/642 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ADGRG3 | c.569A>T p.H190L | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRG4 | c.3589G>T p.V1197F | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ADGRL4 | c.1526G>C p.C509S | Missense Mutation (SNP) | VAF 65/819 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- ADRA1B | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- AFF2 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 70/631 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFF2 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 94/771 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- AFF2 | c.2252G>T p.G751V | Missense Mutation (SNP) | VAF 29/506 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2
- AGBL4 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- AGMO | c.962C>A p.T321N | Missense Mutation (SNP) | VAF 90/768 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AKAP8L | c.1841del p.G614Afs*? | Frame Shift Del (DEL) | VAF 19/109 reads (17%) | called by pindel, varscan2
- AKAP9 | c.11005G>A p.E3669K (on ENST00000359028; = p.E3645K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/807 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- AKR1C8P | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 57/492 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL121899.2 | c.1385del p.P462Qfs*45 | Frame Shift Del (DEL) | VAF 23/146 reads (16%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALDH1L2 | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 50/354 reads (14%) | called by muse, mutect2, varscan2
- ALPK1 | c.2659A>T p.T887S | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- AMD1 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2
- ANK2 | c.10752G>T p.W3584C | Missense Mutation (SNP) | VAF 117/1114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKLE2 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 70/473 reads (15%) | called by muse, mutect2, varscan2
- ANKRD35 | c.2150G>T p.S717I | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.281); called by muse, mutect2
- ANKRD36C | c.1014G>T p.Q338H | Missense Mutation (SNP) | VAF 39/631 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- ANKRD42 | c.982T>A p.Y328N | Missense Mutation (SNP) | VAF 82/618 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKRD60 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKUB1 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- ANP32A | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.289); called by muse, mutect2
- ARFGEF2 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 47/788 reads (6%) | called by muse, mutect2
- ARGFX | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP11A | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARHGAP36 | c.1074C>A p.C358* | Nonsense Mutation (SNP) | VAF 68/317 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.4384C>A p.L1462M | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ARMCX2 | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 87/561 reads (16%) | called by muse, mutect2, varscan2
- ARPP21 | c.2069A>T p.Q690L | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ASAH2 | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 52/1014 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.366); called by muse, mutect2
- ASB9 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ASPM | c.4722A>T p.Q1574H | Missense Mutation (SNP) | VAF 121/772 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ASTN2 | c.2165T>A p.L722Q (on ENST00000313400 / NM_001365069.1; = p.L671Q on NM_014010.5) | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ASXL1 | c.3292G>T p.G1098W | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASXL3 | c.5632T>A p.W1878R | Missense Mutation (SNP) | VAF 63/463 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATP10A | c.1312G>T p.V438F | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ATP13A1 | c.1305G>C p.K435N | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ATP1B4 | c.881G>T p.R294L (on ENST00000218008 / NM_001142447.3; = p.R290L on NM_012069.5) | Missense Mutation (SNP) | VAF 124/743 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ATP2A1 | c.2678C>A p.A893D | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP2B1 | c.1988A>T p.E663V | Missense Mutation (SNP) | VAF 145/865 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ATP2B3 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ATP5MC1 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 93/473 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1517A>G p.D506G | Missense Mutation (SNP) | VAF 48/1032 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- ATP7A | c.4123G>T p.G1375* | Nonsense Mutation (SNP) | VAF 68/578 reads (12%) | called by muse, varscan2
- ATP8A2 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GALT5 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAHCC1 | c.7156G>T p.A2386S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- BCO2 | c.633+1G>T p.X211_splice | Splice Site (SNP) | VAF 29/177 reads (16%) | called by muse, mutect2, varscan2
- BCO2 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- BICC1 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 61/476 reads (13%) | called by muse, mutect2, varscan2
- BRD3 | c.70_71insT p.P24Lfs*52 | Frame Shift Ins (INS) | VAF 15/97 reads (15%) | called by mutect2, pindel, varscan2
- BTNL3 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 54/568 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- BUB1B | c.1216G>T p.G406* | Nonsense Mutation (SNP) | VAF 49/449 reads (11%) | called by muse, mutect2, varscan2
- BUB1B | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 49/453 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C10orf71 | c.412A>T p.K138* | Nonsense Mutation (SNP) | VAF 24/202 reads (12%) | called by muse, varscan2
- C1orf21 | c.328-1G>T p.X110_splice | Splice Site (SNP) | VAF 68/551 reads (12%) | called by muse, mutect2, varscan2
- C8orf76 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1G | c.3565G>T p.G1189C | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CACNA2D1 | c.2868G>T p.E956D (on ENST00000356253 / NM_001366867.1; = p.E944D on NM_000722.4) | Missense Mutation (SNP) | VAF 48/1081 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- CACNG6 | c.546C>A p.G182= (on ENST00000252729 / NM_145814.1; = p.G111= on NM_031897.2) | Splice Region (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- CAGE1 | c.2015G>T p.C672F (on ENST00000512086; = p.C536F on NM_205864.3) | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALD1 | c.2266G>T p.G756* (on ENST00000361675 / NM_033138.4; = p.G501* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 68/528 reads (13%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CAPN14 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- CARS2 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP1 | c.*33G>C | Splice Region (SNP) | VAF 30/305 reads (10%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.5221A>T p.T1741S | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASR | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- CASS4 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 67/500 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CATSPER4 | c.1173C>A p.Y391* | Nonsense Mutation (SNP) | VAF 29/256 reads (11%) | called by muse, mutect2, varscan2
- CCDC168 | c.11137G>T p.G3713C | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CCDC168 | c.10283C>A p.S3428* | Nonsense Mutation (SNP) | VAF 22/359 reads (6%) | called by muse, mutect2
- CCDC170 | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 53/336 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC180 | c.1546-1G>C p.X516_splice | Splice Site (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- CCDC47 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2
- CCNB3 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 31/390 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- CCNB3 | c.3272G>T p.C1091F | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CCSER1 | c.1300G>T p.G434* | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- CD1E | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 139/556 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CD34 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC14A | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 50/596 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.257); called by muse, mutect2
- CDH11 | c.1067C>A p.P356Q | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH18 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDH23 | c.1079T>A p.L360Q | Missense Mutation (SNP) | VAF 68/527 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH23 | c.8669A>G p.Y2890C | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH4 | c.2624C>A p.S875Y | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH7 | c.1840C>A p.L614I | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDH8 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 79/1116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDIPT | c.43+1G>T p.X15_splice | Splice Site (SNP) | VAF 15/199 reads (8%) | called by muse, mutect2
- CDYL | c.773C>A p.P258H (on ENST00000328908 / NM_001368125.1; = p.P204H on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- CENPF | c.1083A>C p.E361D | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CENPI | c.2267A>T p.Y756F | Missense Mutation (SNP) | VAF 85/546 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CFAP47 | c.2367A>C p.L789F | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.099); called by muse, mutect2
- CFAP92 | c.1062G>T p.R354S | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- CHAMP1 | c.2369G>T p.R790L | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CHD5 | c.924T>A p.S308R | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2
- CHFR | c.1442G>T p.S481I (on ENST00000432561 / NM_001161345.1; = p.S440I on NM_018223.2) | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CLCA1 | c.853A>T p.T285S | Missense Mutation (SNP) | VAF 96/856 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CLTC | c.1561G>T p.V521L | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CNDP2 | c.1312G>T p.G438W | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CNGA2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNOT1 | c.5404G>T p.A1802S | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNTNAP2 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL18A1 | c.3241G>T p.G1081C (on ENST00000359759 / NM_130444.3; = p.G846C on NM_030582.4) | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- COL22A1 | c.4645G>C p.A1549P | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- COL4A2 | c.1597-1G>C p.X533_splice | Splice Site (SNP) | VAF 53/489 reads (11%) | called by muse, mutect2, varscan2
- COL4A5 | c.1610C>G p.A537G | Missense Mutation (SNP) | VAF 129/918 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- COL4A6 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CPED1 | c.342del p.H115Tfs*5 | Frame Shift Del (DEL) | VAF 29/231 reads (13%) | called by mutect2, pindel, varscan2
- CRB1 | c.3869C>T p.T1290I | Missense Mutation (SNP) | VAF 116/698 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CRYBG2 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSMD3 | c.918-1G>A p.X306_splice | Splice Site (SNP) | VAF 85/562 reads (15%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2488G>T p.G830W | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTNNA3 | c.2201C>A p.A734E | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CTNND2 | c.2191A>T p.R731* | Nonsense Mutation (SNP) | VAF 57/456 reads (13%) | called by muse, mutect2, varscan2
- CTNND2 | c.192G>C p.R64S | Missense Mutation (SNP) | VAF 93/536 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CTRL | c.52+3G>A | Splice Region (SNP) | VAF 44/244 reads (18%) | called by muse, mutect2, varscan2
- CXADR | c.525G>T p.W175C | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CXorf38 | c.841A>G p.N281D | Missense Mutation (SNP) | VAF 26/335 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- CYLC1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.038); called by muse, mutect2
- CYP2D7 | c.78C>G p.H26Q | Missense Mutation (SNP) | VAF 17/369 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- DACH2 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DACH2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DACH2 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 61/381 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- DACT1 | c.2341G>T p.G781C | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACT3 | c.516C>G p.S172R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DBF4B | c.1666G>T p.V556F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2
- DCAF12L1 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- DCAF12L2 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 74/365 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCDC1 | c.3461C>A p.P1154Q (on ENST00000597505 / NM_001367979.1; = p.P261Q on NM_020869.3) | Missense Mutation (SNP) | VAF 92/529 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DCLK2 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- DCLK3 | c.1924A>T p.R642W | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- DCLRE1C | c.1831G>T p.D611Y (on ENST00000378278 / NM_001350965.2; = p.D496Y on NM_022487.4) | Missense Mutation (SNP) | VAF 49/758 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2
- DCPS | c.194A>C p.H65P | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DCX | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 163/914 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DDB1 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 19/366 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.347); called by muse, mutect2
- DDX54 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- DEPDC5 | c.2308G>T p.E770* (on ENST00000400246; = p.E839* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 36/311 reads (12%) | called by muse, mutect2, varscan2
- DGKK | c.2232T>A p.D744E | Missense Mutation (SNP) | VAF 102/931 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DHX35 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.32); called by muse, mutect2
- DLX1 | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- DLX6 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2
- DMD | c.9321G>T p.R3107S | Missense Mutation (SNP) | VAF 88/988 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMP1 | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- DNAAF5 | c.1112G>T p.W371L | Missense Mutation (SNP) | VAF 77/471 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- DNAH11 | c.7406C>A p.A2469D | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DNAH3 | c.9866A>T p.E3289V | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DNAH3 | c.5131G>T p.D1711Y | Missense Mutation (SNP) | VAF 26/337 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); called by muse, mutect2
- DOCK11 | c.3001C>A p.L1001M | Missense Mutation (SNP) | VAF 142/758 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DOCK4 | c.2738G>T p.G913V | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, varscan2
- DOT1L | c.1220C>G p.A407G | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DPPA2 | c.581C>G p.A194G | Missense Mutation (SNP) | VAF 44/415 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- DSG4 | c.1358A>T p.D453V | Missense Mutation (SNP) | VAF 116/480 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- EDNRB | c.1464+3A>T | Splice Region (SNP) | VAF 59/579 reads (10%) | called by muse, mutect2, varscan2
- EEF1G | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- EEF2K | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EFHB | c.2354G>A p.G785D | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- EHBP1L1 | c.4473C>G p.I1491M | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- EHD4 | c.1430C>A p.S477Y | Missense Mutation (SNP) | VAF 15/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- EIF2AK3 | c.2434G>T p.G812C | Missense Mutation (SNP) | VAF 120/850 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELFN1 | c.1478C>A p.A493D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- EMILIN2 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ENPP7 | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ENTPD1 | c.62T>A p.L21H | Missense Mutation (SNP) | VAF 114/1009 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EPB41L2 | c.603G>T p.E201D | Missense Mutation (SNP) | VAF 80/1285 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2
- EPB41L3 | c.2678A>T p.E893V | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- EPHA3 | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- EPHA3 | c.1512A>G p.I504M | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ERICH3 | c.2938C>A p.P980T | Missense Mutation (SNP) | VAF 62/586 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- ERVW-1 | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by mutect2, varscan2
- ESPNL | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ESX1 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EWSR1 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EYS | c.1334G>T p.C445F | Missense Mutation (SNP) | VAF 79/786 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM102B | c.289-1G>T p.X97_splice | Splice Site (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2
- FAM120B | c.2702A>T p.Q901L | Missense Mutation (SNP) | VAF 22/524 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); called by muse, mutect2
- FAM120C | c.1682G>T p.W561L | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.084); called by muse, mutect2
- FAM120C | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, varscan2
- FAM124B | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FAM135B | c.2128G>T p.D710Y | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FAM160A2 | c.1876G>T p.G626C (on ENST00000449352 / NM_001098794.2; = p.G640C on NM_032127.4) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- FAM20C | c.1072+1G>A p.X358_splice | Splice Site (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- FAM47A | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.11); called by muse, mutect2
- FAM47B | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- FAM47B | c.490G>C p.A164P | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAM71A | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM83B | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 65/544 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCB | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); called by muse, mutect2
- FANCB | c.157G>T p.G53* | Nonsense Mutation (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- FAT2 | c.9251T>A p.V3084D | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.2168C>A p.P723Q | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT3 | c.11355C>A p.C3785* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- FAT4 | c.12427G>T p.G4143* | Nonsense Mutation (SNP) | VAF 59/404 reads (15%) | called by muse, mutect2, varscan2
- FBF1 | c.781G>T p.E261* (on ENST00000586717; = p.E275* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- FBH1 | c.1360G>T p.E454* (on ENST00000362091 / NM_178150.3; = p.E505* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 63/518 reads (12%) | called by muse, mutect2, varscan2
- FBLN2 | c.1262C>G p.T421R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- FBN1 | c.4508T>C p.V1503A | Missense Mutation (SNP) | VAF 60/1200 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2
- FBN2 | c.4798G>T p.G1600C | Missense Mutation (SNP) | VAF 99/416 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXL7 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by mutect2, varscan2
- FBXO22 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- FCRL2 | c.1308-2A>T p.X436_splice | Splice Site (SNP) | VAF 80/341 reads (23%) | called by muse, mutect2, varscan2
- FCRL3 | c.1838+1G>C p.X613_splice | Splice Site (SNP) | VAF 71/670 reads (11%) | called by muse, mutect2, varscan2
- FCRL4 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2
- FCRLA | c.388C>A p.L130M (on ENST00000367959; = p.L107M on NM_032738.4) | Missense Mutation (SNP) | VAF 72/403 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD5 | c.1932C>G p.D644E | Missense Mutation (SNP) | VAF 59/461 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FIGN | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 79/770 reads (10%) | PolyPhen probably damaging (0.98); called by muse, mutect2
- FLNA | c.2752del p.D918Mfs*28 | Frame Shift Del (DEL) | VAF 66/347 reads (19%) | called by mutect2, pindel, varscan2
- FLVCR1 | c.1413G>T p.Q471H | Missense Mutation (SNP) | VAF 94/738 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FLVCR1 | c.1413+1G>T p.X471_splice | Splice Site (SNP) | VAF 94/766 reads (12%) | called by muse, mutect2, varscan2
- FOLR2 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 87/511 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FOXB1 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- FOXD3 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.111); called by muse, mutect2
- FOXK1 | c.1200G>T p.R400S | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRAS1 | c.7018G>T p.A2340S | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD4 | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- FRY | c.2996+1G>T p.X999_splice | Splice Site (SNP) | VAF 19/379 reads (5%) | called by muse, mutect2
- GABRA2 | c.1036G>T p.G346W | Missense Mutation (SNP) | VAF 56/623 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRA2 | c.468T>A p.Y156* | Nonsense Mutation (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- GABRB2 | c.1438G>T p.D480Y (on ENST00000274547; = p.D442Y on NM_000813.3) | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- GABRD | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 89/474 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GABRG3 | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GABRR1 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- GATAD2A | c.1503C>T p.V501= | Splice Region (SNP) | VAF 11/208 reads (5%) | called by muse, mutect2
- GC | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 64/680 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2
- GCGR | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDI1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GDPD4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 69/435 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GJA5 | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 126/655 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLUD2 | c.1150A>C p.T384P | Missense Mutation (SNP) | VAF 187/1058 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- GOLGA6L10 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 138/1352 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GOLGA6L2 | c.323C>A p.T108K | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.462); called by muse, mutect2
- GPN1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 80/635 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GPR27 | c.1024A>T p.N342Y | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR6 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRIN3 | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GREB1L | c.2936G>T p.R979L | Missense Mutation (SNP) | VAF 100/506 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GRIA3 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 17/485 reads (4%) | called by muse, mutect2
- GRIA3 | c.2049C>A p.D683E | Missense Mutation (SNP) | VAF 152/1074 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRID2 | c.1348-1G>T p.X450_splice | Splice Site (SNP) | VAF 40/380 reads (11%) | called by muse, varscan2
- GRID2IP | c.199C>G p.R67G | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.067); called by muse, mutect2
- GRIN2D | c.1867G>T p.G623C | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIP2 | c.2614C>A p.P872T (on ENST00000619221; = p.P775T on NM_001080423.4) | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- GRM5 | c.2426G>A p.S809N | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GSDME | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 84/683 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- GYS2 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 139/955 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAL | c.1471G>C p.G491R | Missense Mutation (SNP) | VAF 133/655 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAUS5 | c.1584G>T p.Q528H | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HAVCR1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HCRTR1 | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HDAC2 | c.323_324del p.F108* | Frame Shift Del (DEL) | VAF 75/645 reads (12%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- HERC2 | c.5462T>A p.I1821N | Missense Mutation (SNP) | VAF 41/538 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- HLA-DPA1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- HLX | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.36); called by muse, varscan2
- HMCN2 | c.9350C>T p.A3117V | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.941del p.G314Vfs*3 (on ENST00000354667 / NM_031243.3; = p.G302Vfs*3 on NM_002137.4) | Frame Shift Del (DEL) | VAF 62/520 reads (12%) | called by mutect2, pindel, varscan2
- HS3ST2 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HTR1A | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- HTR1A | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 185/1197 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- HUS1B | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- IGKV1D-42 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 56/439 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- IGKV2D-26 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- IGKV6-21 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 19/323 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- IL1RAPL1 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); called by muse, mutect2
- IL1RL1 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IL3RA | c.327T>A p.N109K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2
- IL6 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IMPG2 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 54/502 reads (11%) | called by muse, mutect2, varscan2
- ING2 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 56/588 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2
- INPP4B | c.2711A>G p.Q904R | Missense Mutation (SNP) | VAF 55/579 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- INPP4B | c.1728G>T p.W576C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- INSIG1 | c.805-1G>T p.X269_splice | Splice Site (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- IQSEC2 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IRS4 | c.1738C>A p.H580N | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ITGA5 | c.1287dup p.G430Wfs*9 | Frame Shift Ins (INS) | VAF 30/184 reads (16%) | called by mutect2, pindel
- ITIH5 | c.1521C>A p.F507L | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPRID2 | c.2804G>T p.G935V | Missense Mutation (SNP) | VAF 53/539 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- JADE3 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 44/618 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.281); called by muse, mutect2
- JAKMIP3 | c.1750-1G>T p.X584_splice | Splice Site (SNP) | VAF 32/145 reads (22%) | called by muse, mutect2, varscan2
- JHY | c.419A>T p.Q140L | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KANK3 | c.1741C>A p.Q581K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- KCND2 | c.1648C>G p.Q550E | Missense Mutation (SNP) | VAF 55/829 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- KCNE5 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KCNH8 | c.676T>A p.W226R | Missense Mutation (SNP) | VAF 88/929 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KCNH8 | c.1827G>A p.G609= | Splice Region (SNP) | VAF 21/220 reads (10%) | called by muse, mutect2
- KCNJ3 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- KCNMA1 | c.3694C>A p.Q1232K (on ENST00000286628 / NM_001161352.2; = p.Q1174K on NM_002247.4) | Missense Mutation (SNP) | VAF 83/734 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNQ2 | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNQ2 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCTD7 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/268 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.692); called by muse, mutect2
- KDM1B | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 60/494 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KDM4E | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.757); called by muse, mutect2
- KERA | c.130A>T p.M44L | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- KIAA0586 | c.3041A>C p.Q1014P (on ENST00000619416 / NM_001244190.2; = p.Q953P on NM_014749.5) | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- KIAA1671 | c.3415G>T p.G1139C | Missense Mutation (SNP) | VAF 76/470 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- KIF26A | c.1411A>G p.M471V | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF7 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLF12 | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 91/580 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL23 | c.1491G>C p.R497S | Missense Mutation (SNP) | VAF 87/636 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- KLHL34 | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- KLK3 | c.93C>A p.C31* | Nonsense Mutation (SNP) | VAF 53/264 reads (20%) | called by muse, mutect2, varscan2
- KRBA1 | c.2819G>T p.S940I | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- KRBOX1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- KRT14 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- KRT74 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 187/820 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT77 | c.1381del p.V461Wfs*25 | Frame Shift Del (DEL) | VAF 104/404 reads (26%) | called by mutect2, pindel, varscan2
- KRT78 | c.785G>T p.S262I | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- L1CAM | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2
- LAMA1 | c.4411G>T p.D1471Y | Missense Mutation (SNP) | VAF 132/977 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- LAMA5 | c.4630G>T p.D1544Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMB1 | c.4499T>A p.L1500Q | Missense Mutation (SNP) | VAF 104/730 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMB2 | c.3695G>T p.W1232L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- LANCL1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2
- LANCL1 | c.174T>A p.D58E | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- LARP6 | c.1419G>T p.R473S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.578); called by muse, mutect2
- LARS1 | c.2224G>T p.A742S (on ENST00000394434 / NM_020117.11; = p.A715S on NM_016460.3) | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- LATS2 | c.2632A>T p.N878Y | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCP2 | c.189G>A p.P63= | Splice Region (SNP) | VAF 46/400 reads (12%) | called by muse, mutect2, varscan2
- LCT | c.4663+1G>T p.X1555_splice | Splice Site (SNP) | VAF 84/663 reads (13%) | called by muse, mutect2, varscan2
- LHFPL3 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LHX4 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- LPA | c.5405C>A p.S1802Y | Missense Mutation (SNP) | VAF 30/570 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.362); called by muse, mutect2
- LRP1 | c.8576G>T p.G2859V | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP2 | c.12988+1G>A p.X4330_splice | Splice Site (SNP) | VAF 104/580 reads (18%) | called by muse, mutect2, varscan2
- LRRC4C | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC53 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 68/510 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- LRRC53 | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); called by muse, mutect2
- LRRC63 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 46/604 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2
- LTBP1 | c.2789G>T p.R930L (on ENST00000404816 / NM_206943.4; = p.R604L on NM_000627.4) | Missense Mutation (SNP) | VAF 94/694 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- LUZP2 | c.701C>A p.T234N | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2
- LYAR | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- LYN | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- LYPD8 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 93/631 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAGEA11 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 23/416 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- MAGEB18 | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.286); called by muse, mutect2
- MAGEB4 | c.973C>A p.R325S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by mutect2, varscan2
- MAGEB6B | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- MAGEE1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 31/205 reads (15%) | called by muse, mutect2, varscan2
- MAGEE1 | c.2643G>T p.Q881H | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MALRD1 | c.3372C>A p.S1124R | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- MALT1 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 78/457 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MAN2A1 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- MANBA | c.1724G>T p.G575V (on ENST00000642252; = p.G529V on NM_005908.4) | Missense Mutation (SNP) | VAF 73/711 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K5 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAP3K8 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MAP4K4 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 36/305 reads (12%) | called by muse, mutect2, varscan2
- MAP7D2 | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 61/636 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.253); called by muse, mutect2
- MAP7D3 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 27/494 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- MAPK4 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- MARK1 | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MARK2 | c.1676+6T>A | Splice Region (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- MARS2 | c.1701G>T p.R567S | Missense Mutation (SNP) | VAF 60/630 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2
- MAS1L | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 27/445 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2
- MB21D2 | c.1100A>T p.H367L | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MBL2 | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCCC2 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 154/889 reads (17%) | called by muse, mutect2, varscan2
- MCF2 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2
- MEIG1 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 90/741 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MIA2 | c.1381C>A p.H461N | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MIGA1 | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.066); called by muse, mutect2
- MMP13 | c.93G>T p.L31F | Missense Mutation (SNP) | VAF 143/1254 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP16 | c.1235G>T p.W412L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP2 | c.500C>A p.A167E | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MOGAT3 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MS4A1 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 116/772 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A1 | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 117/767 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A2 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); called by muse, mutect2
- MSH3 | c.863A>T p.H288L | Missense Mutation (SNP) | VAF 132/965 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSRB3 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 178/1131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTSS1 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 79/633 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC12 | c.949C>G p.P317A (on ENST00000379442; = p.P174A on NM_001164462.1) | Missense Mutation (SNP) | VAF 65/481 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MUC17 | c.5999C>A p.S2000Y | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MUC2 | c.1881C>G p.C627W | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUCL1 | c.124_125delinsT p.P42Lfs*55 | Frame Shift Del (DEL) | VAF 77/514 reads (15%) | called by pindel, varscan2*
- MXRA5 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH3 | c.3661G>T p.E1221* | Nonsense Mutation (SNP) | VAF 83/582 reads (14%) | called by muse, mutect2, varscan2
- MYH9 | c.2927T>C p.L976P | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- MYO10 | c.5966G>A p.R1989K | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO16 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
873 further variants in this file (331 protein-altering or splice-affecting, 332 silent, 210 other) are not listed here.
